Surgical pathology report (de-identified scan), TCGA case TCGA-IZ-A6M8, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site ABS - Lahey Clinic, specimen TCGA-IZ-A6M8-01A (Primary Tumor).

[page 1 of 4]
MRN
Name
Encounter Number

Gender M
Date Of Birth

COPY ONLY DO NOT FILE

SURGICAL PATHOLOGY

Time Collected
Time Reported
Ordering Provider
Status

Time Received
Order Number

Final

Results

Final

Source of Specimen
RIGHT KIDNEY PROXIMAL URETER-

FINAL DIAGNOSIS:
RIGHT KIDNEY PROXIMAL URETER-
RENAL CELL CARCINOMA, LIMITED TO KIDNEY. SEE SYNOPTIC REPORT.

SIMPLE CORTICAL CYSTS.

SYNOPTIC REPORT:

RENAL CELL CARCINOMA.

PROPORTION OF SARCOMATOID COMPONENT: 0 %.

SPECIMEN LATERALITY: RIGHT.

TUMOR FOCALITY: FOCAL.

TUMOR SIZE (LARGEST TUMOR, IF MULTIPLE): 2.5 CM.

HISTOLOGIC TYPE: PAPILLARY TYPE.

HISTOLOGIC GRADE (FUHRMAN NUCLEAR GRADE): 2/4.

TNM STAGE: pT1a, pNX, pMX.

(T1a: not > 4 cm; T1b: not > 7 cm; T2a: not > 10 cm; T2b: > 10 cm)

(N0: negative node; N1: regional nodes)

Prepared for

ICD-0-3

Carcinoma, papillary
renal cell 8260/3

Site R Kidney NOS
C64.9

JW 7/24/13

[page 2 of 4]
LYMPH NODE(S) INCLUDED IN ALL PARTS: NONE SUBMITTED.

LYMPHATIC (SMALL VESSEL) INVASION: IS NOT SEEN.

SPECIMEN TYPE: RIGHT RADICAL NEPHRECTOMY.

SPECIMEN SIZE: 18.0 x 10.0 x 7.0 CM (OVERALL) AND KIDNEY PROPER
9.0 x 5.0 x 4.0 CM.

ADRENAL GLAND: N/A.

NO TUMOR SEEN AT RESECTION MARGINS.

Comment

EVALUATION OF NON-NEOPLASTIC RENAL PARENCHYMA:

DIFFUSE AND EARLY NODULAR MESANGIAL SCLEROSIS, MOST LIKELY AN
EXPRESSION OF EARLY DIABETIC GLOMERULOSCLEROSIS

ADVANCED CHRONIC CHANGES OF THE KIDNEY PARENCHYMA, INCLUDING:

- FOCAL GLOBAL GLOMERULOSCLEROSIS (80% OF GLOMERULI)
- TUBULAR ATROPHY AND INTERSTITIAL FIBROSIS (>60% OF THE PARENCHYMA)
- ARTERIAL AND ARTERIOLAR SCLEROSIS, MODERATE, WITH SUBCAPSULAR VASCULAR SCARS

JONES, PAS AND TRICHROME EXAMINED.

Signature

(Case signed

Case Clinical Information

BILATERAL RENAL CELL CARCINOMA

Gross Description

Received in formalin labeled with the patient's name and "right kidney and proximal ureter" is a previously inked and bivalved 400 gram total nephrectomy specimen with attached perinephric fat. Overall dimensions of the specimen are 18 x 10 x 7 cm. The kidney proper measures 9 x 4 x 5 cm. The vessels at the hilum are identified. The ureter is identified and measures 2 cm in length. Grossly, no lymph nodes are identified at the hilum. On the bivalved kidney, the cut surface is remarkable for an encapsulated, circumscribed, tan/yellow mass measuring

Prepared for

[page 3 of 4]
2.5 x 2 x 2 cm. The mass grossly appears to be pushing the capsule. Adjacent to the mass is a 2.5 cm cystic structure that is lined with a tan, glistening and grossly unremarkable tissue with no excrescences. The mass measures to the UP junction of the specimen 3.8 cm. The remainder of the cut surface reveals several additional cortical cystic structures ranging in size from 0.8 cm down to 0.2 cm. Further sectioning the kidney, on the opposite pole of the mass the cut surface reveals a smooth 0.5 cm nodule measuring to the capsule and fatty tissue 0.8 cm. The remainder of the cut surface is grossly unremarkable. No adrenal gland was identified in the specimen. Representative sections are submitted as follows: A1=right ureter resection margin; A2=remainder of vessels at hilum; A3-A7=entire mass demonstrating mass to capsule and fat; A8, A9=representative sections of cystic structure adjacent to mass previously described; A10=representative section of additional smaller nodule; A11=representative section of additional smaller cortical cyst; A12=representative section of UP junction tissue, A13= ureter.

Physicians

Procedure

A. AA ROUTINE H&E X1 BLOCK.1
H&E X1 A RECUTS
A. AA ROUTINE H&E X1 BLOCK.2
H&E X1
A. AA ROUTINE H&E X1 BLOCK.3
H&E X1
A. AA ROUTINE H&E X1 BLOCK.4
H&E X1
A. AA ROUTINE H&E X1 BLOCK.5
H&E X1
A. AA ROUTINE H&E X1 BLOCK.6
H&E X1
A. AA ROUTINE H&E X1 BLOCK.7
H&E X1
A. AA ROUTINE H&E X1 BLOCK.8
H&E X1
A. AA ROUTINE H&E X1 BLOCK.9
H&E X1
A. AA ROUTINE H&E X1 BLOCK.10
H&E X1 JONES PAS TRICHROME
A. AA ROUTINE H&E X1 BLOCK.11
H&E X1
A. AA ROUTINE H&E X1 BLOCK.12

Prepared for

[page 4 of 4]
H&E X1
A. AA ROUTINE H&E X1 BLOCK.13
H&E X1

Prepared for:

Per TSS, Patient received no chemo or radiation for either prior/synchronous malignancy. BCR

Source: NCI Genomic Data Commons file 5fc45b53-4f22-4c28-9b83-dcae25c6faf8 (TCGA-IZ-A6M8.7C3F1077-05AC-498F-A09B-37833A70031B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).